Surgical pathology report (de-identified scan), TCGA case TCGA-ZG-A9LS, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site University Medical Center Hamburg-Eppendorf, specimen TCGA-ZG-A9LS-01A (Primary Tumor).

[page 1 of 2]
Histopathological Report

Date of cancer sample procurement:

Date of pathology report:

Patient ID:

Gross description:

1. (Prostate gland): Prostate gland: Weight: 40 g, Volume: 35 ml, Size: 5.5 x 5 x 4.2 cm. Adherent seminal vesicles and deferent duct: right side: 2 cm, left side: 2.5 cm. The surface is marked with green ink on the right side, blue ink on the left side. On the right recto-lateral surface a 4 x 3.5 cm measuring tissue defect marked with yellow ink. On the left recto-lateral surface a 4.5 x 4.6 cm measuring tissue defect marked with yellow ink. Apical peri-urethral a funnel shaped 1 x 0.9 cm tissue defect marked with red ink. On the anterior side a 1.5 x 1 cm tissue defect marked with black ink. Total of the cross sections: 1.7 cm.
2. (Pre-prostatic fat): 2 x 2.2 cm measuring adipose tissue without palpable nodes.
3. (Lymph nodes, right side): 12 x 8 x 1.7 cm measuring adipose tissue containing 5 nodes measuring up to 1 x 1 x 0.5 cm.
4. (Lymph nodes, left side): 11.2 x 9.5 x 1.7 cm measuring adipose tissue containing 5 nodes measuring up to 1.5 x 1 x 0.7 cm.
5. (Neurovascular bundle, left side): Soft tissue measuring 2.7 x 2 x 0.5 cm.

Microscopy:

1. Apex right and left: Right 4 tissue blocks, left 5 tissue blocks (total 9 tissue blocks). 4 cross sections: Right 8 tissue blocks, left 8 tissue blocks (total 16 tissue blocks). Basis right and left: Right 4 tissue blocks, left 4 tissue blocks (total 8 tissue blocks). Seminal vesicles right and left: Right 3 tissue blocks, left 3 tissue blocks (total 6 tissue blocks). Deferent ducts right and left: Right 1 tissue block, left 1 tissue block (total 2 tissue blocks).
2. Pre-prostatic fat: 1 tissue block.
3. Frozen lymph nodes right: 10 tissue blocks.
4. Frozen lymph nodes left: 11 tissue blocks.
5. (Neurovascular bundle, left side): 3 tissue blocks.

ICD-O-3
Adenocarcinoma NOS 8140/3
Site: Prostate NOS C61.9
JW 1/22/14

Diagnosis:

1. (Prostate gland): Poorly differentiated prostatic adenocarcinoma, Gleason 5+4=9, (Gleason 5: 70%, Gleason 4: 30%). Tumor involves both lobes with the main focus on the left side. Maximum tumor diameter: 55 mm. Extensive perineural invasion. Tumor infiltration into peri-prostatic adipose tissue in 12 tissue blocks, thereof 3 adjacent blocks with the main focus around the left base (maximum invasion length 8 mm, maximal invasion depth 1.5 mm). Tumor infiltration into the right seminal vesicle. Positive surgical margin in 1 block, right apex (contact length 0.1 mm; Gleason 4).

[page 2 of 2]
Remaining prostatic tissue with small foci of prostatic intraepithelial neoplasia (high grade PIN) and signs of myoglandular hyperplasia of the prostate. Urothelium of the prostatic urethra without dysplasia. Tumor-free left seminal vesicle and deferent ducts.

2. Pre-prostatic fat: Tumor-free soft tissue containing nerves and blood vessels.
3. (Lymph nodes, right side): Three lymph node metastases in 26 lymph nodes (3/26).
4. (Lymph nodes, left side): 21 tumor-free lymph nodes (0/21).
5. (Neurovascular bundle, left side): Soft tissue with focal tumor infiltration.

Tumor classification

(in consideration of the intraoperative frozen-section and immunohistochemical analyses):

pT3b, Gleason 5+4=9 (Gleason 5: 68%, Gleason 4: 32%), maximum tumor diameter: 55 mm, tumor volume approx. 28.4 ml (Gleason 5: 19.3 ml, Gleason 4: 9.1 ml), pN1 (3/47), L1, V0, R1

Comments:

The preceding intraoperative frozen section showed more adenocarcinoma on the left side with positive surgical margin. The consequently resected left neurovascular bundle showed a minor tumor focus.

The preceding punch biopsy contained prostatic adenocarcinoma, Gleason 5+4=9.

Immunohistochemical analyses (D2-40, CD31) on tissue blocks LA2 and LP2 revealed lymphatic invasion, but no venous invasion.

One macroscopic image for tumor mapping.

Source: NCI Genomic Data Commons file 16f7ace0-0fad-4509-900d-60bccabaf5d7 (TCGA-ZG-A9LS.C08F26E6-5CC1-42FC-9533-D4199A5CE8B4.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).